TCGA case TCGA-XR-A8TG — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: University of Sao Paulo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d7d5166-6582-4ea1-b242-37c2c3919a3c

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Brazil; Age at index: 58 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 59.0 years (21,544 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 898 days (2.5 years); Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 48.4 years (17,671 days); Days to diagnosis: -3,873 days (-10.6 years); AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 59.9 years (21,894 days); Days to diagnosis: 350 days; Prior treatment: Yes.
   Treatment given: Treatment type: Organ Transplantation; Initial disease status: Recurrent Disease; Days to treatment start: 713 days (2.0 years); Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 350 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 350 days.
- Days to follow up: 867 days (2.4 years); Disease response: Tumor Free.
- Days to follow up: 898 days (2.5 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Total Bilirubin 0.5 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0; Blood test normal range upper: 1.5].
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 4.8].
- Platelets 80000 (unit not recorded by GDC) [Blood test normal range lower: 150000; Blood test normal range upper: 450000].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.5].
- Alpha Fetoprotein 1 ng/mL [Blood test normal range lower: 6; Blood test normal range upper: 6].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 71 kg; Height: 184 cm; BMI: 21.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis C Infection.

Family history
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XR-A8TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-XR-A8TG-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-XR-A8TG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XR-A8TG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; Hepatic inflammation adj tissue: Mild.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Melanoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 898 days; disease-specific survival: no event (censored), 898 days; disease-free interval: event (new tumor event after initially disease-free), 350 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 350 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XR-A8TG-01A-11D-A35Y-01): tumor purity 0.79, ploidy 2.04, whole-genome doublings 0.
